Gene-level copy-number profile of tumor specimen TCGA-LN-A4A1-01A from TCGA case TCGA-LN-A4A1, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle third of esophagus; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 60.1 years (21,954 days).
Specimen TCGA-LN-A4A1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.0b49f456-11a0-4a0b-86f2-8e21d5d9b637.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-LN-A4A1-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2.
https://portal.gdc.cancer.gov/files/950cec43-0c57-4d15-9520-cf1c0f067fb0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 111; copy number 1: 1,491; copy number 2: 23,971; copy number 3: 14,569; copy number 4: 14,348; copy number 5: 3,081; copy number 6: 497; copy number 7: 391; copy number 8: 779; copy number 9: 554; copy number 14: 19.

Homozygous deletions (total copy number 0; autosomes only): 111 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,140,391–119,327,915, 3 genes (within-gene range 0–2): WARS2-AS1, RPL6P2, AL359915.1.
- chr3:54,874,605–54,967,088, 2 genes: CACNA2D3-AS1, LRTM1.
- chr3:59,050,164–59,754,808, 5 genes (within-gene range 0–1): AC126121.3, AC138057.1, AC126121.2, AC126121.1, Metazoa_SRP.
- chr3:59,809,269–59,811,310, 1 gene: AC093418.1.
- chr4:94,451,857–94,668,227, 1 gene (within-gene range 0–2): PDLIM5.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–2): MTAP, AL359922.1.
- chr9:21,892,188–22,214,672, 11 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr10:74,151,202–74,709,963, 1 gene (within-gene range 0–2): ADK.
- chr10:74,371,535–74,656,131, 7 genes: RPSAP6, RAB5CP1, AC022540.1, MRPL35P3, Y_RNA, NDUFA8P1, POLR3DP1.
- chr10:87,945,502–90,225,443, 54 genes: RPL11P3, AC063965.1, MED6P1, AL353149.1, RNLS, Y_RNA, LIPJ, RPL7P34, LIPF, NAPGP1, LIPK, KRT8P38, LIPN, RCBTB2P1, LIPM, ANKRD22, PTCD2P2, STAMBPL1, ACTA2-AS1, ACTA2, AL157394.3, FAS, AL157394.2, AL157394.1, MIR4679-2, MIR4679-1, AL513533.1, CH25H, LIPA, IFIT2, AL353751.1, IFIT3, IFIT6P, IFIT1B, IFIT1, IFIT5, SLC16A12, SLC16A12-AS1, PANK1, MIR107, AL157400.5, AL157400.2, AL157400.1, AL157400.3, AL157400.4, KIF20B, MTND5P42, LINC00865, MARK2P16, LINC01374, LINC01375, SNRPD2P1, AL139340.1, RN7SKP143.
- chr11:15,966,449–16,739,591, 1 gene (within-gene range 0–2): SOX6.
- chr11:16,484,084–16,484,671, 1 gene: AKR1B1P3.
- chr16:78,890,231–78,899,644, 2 genes: AC027279.4, AC027279.1.
- chr17:17,843,511–17,972,422, 1 gene (within-gene range 0–2): TOM1L2.
- chr17:29,560,547–29,930,276, 19 genes (within-gene range 0–2): ABHD15, ABHD15-AS1, TP53I13, AC104564.3, GIT1, ANKRD13B, AC104564.4, CORO6, AC104564.2, SSH2, AC104564.1, RNU6-920P, AC104564.5, RPL21P123, AC023389.1, AC023389.2, SNORA70, RPL9P30, AC104982.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 5,321 genes in 25 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–4,424,689, 210 genes, copy number 5 (broad region; genes not listed).
- chr1:143,343,180–152,985,500, 399 genes, copy number 5 (broad region; genes not listed).
- chr1:242,671,140–248,601,869, 176 genes, copy number 5–7 (broad region; genes not listed).
- chr2:134,028,608–135,047,468, 14 genes, copy number 5 (within-gene range 3–5): AC092623.1, MGAT5, MIR3679, RNA5SP104, EDDM3CP, TMEM163, AC110620.2, CCNT2-AS1, VDAC2P4, AC110620.1, ACMSD, MIR5590, CCNT2, MAP3K19.
- chr2:165,194,993–184,187,573, 306 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr2:190,534,855–191,425,389, 19 genes, copy number 5 (within-gene range 3–5): AC108047.1, RN7SKP179, AC006460.2, NAB1, AC006460.1, AC005540.1, GLS, STAT1, RAB1AP1, AC067945.1, AC067945.2, STAT4, AC067945.3, RNU6-959P, AC079777.1, HMGB1P27, AC092614.1, MYO1B, RNU6-1045P.
- chr3:93,843,764–180,989,774, 1,398 genes, copy number 5 (broad region; genes not listed).
- chr3:181,534,177–188,154,057, 175 genes, copy number 5 (broad region; genes not listed).
- chr3:188,178,543–188,180,812, 1 gene, copy number 5: FLJ42393.
- chr3:188,941,715–198,222,513, 217 genes, copy number 5 (broad region; genes not listed).
- chr5:165,349,030–168,264,157, 18 genes, copy number 5 (within-gene range 4–5): AC008415.1, RN7SKP60, AC008562.1, AC008489.1, RPL7P20, AC114321.1, AC026403.1, LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1, AC008464.1, AC008705.2.
- chr7:70,972–7,718,607, 188 genes, copy number 6 (broad region; genes not listed).
- chr7:7,735,743–7,742,574, 2 genes, copy number 6: AC007161.2, AC007161.1.
- chr7:7,968,796–8,094,272, 1 gene, copy number 7 (within-gene range 4–7): GLCCI1.
- chr7:8,113,184–24,981,634, 200 genes, copy number 7 (broad region; genes not listed).
- chr7:75,899,200–76,627,982, 28 genes, copy number 6 (within-gene range 4–6): POR, RPL7L1P3, SNORA14A, TMEM120A, STYXL1, AC006330.1, MDH2, AC005077.4, RNU6-863P, GTF2IP7, AC005077.2, AC005077.1, AC005077.3, SRRM3, HSPB1, YWHAG, PPIAP81, SSC4D, ZP3, DTX2, FDPSP2, AC005522.1, UPK3B, AC004980.4, Y_RNA, AC004980.3, SPDYE16, AC004980.1.
- chr7:87,627,548–111,562,517, 484 genes, copy number 7–14 (within-gene range 2–14) (broad region; genes not listed).
- chr8:85,642,777–88,887,573, 49 genes, copy number 7: REXO1L8P, REXO1L3P, REXO1L1P, REXO1L12P, REXO1L11P, REXO1L10P, REXO1L9P, REXO1L2P, AC232323.1, REXO1L4P, REXO1L5P, REXO1L6P, AC100801.1, LINC02849, AC100801.2, ATP6V0D2, AC023194.1, AC023194.2, PSKH2, AC023194.3, AC084128.1, SLC7A13, AC103760.1, WWP1, RMDN1, NTAN1P2, SLC2A3P4, CPNE3, CNGB3, MIOXP1, GOLGA2P1, UBE2Q2P10, AC090572.3, AC090572.2, AC090572.1, CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2, AC037450.1, MMP16, AC090578.1, RNA5SP272, AC090568.1, AC090578.2, AC090578.3.
- chr8:89,757,806–99,877,580, 174 genes, copy number 7–8 (within-gene range 4–8) (broad region; genes not listed).
- chr8:99,796,615–145,066,685, 714 genes, copy number 8 (broad region; genes not listed).
- chr11:67,711,702–71,603,353, 113 genes, copy number 6–9 (broad region; genes not listed).
- chr12:66,767–6,946,003, 203 genes, copy number 6 (broad region; genes not listed).
- chr12:64,507,001–64,697,564, 1 gene, copy number 5 (within-gene range 3–5): RASSF3.
- chr12:64,599,078–73,208,317, 167 genes, copy number 5 (broad region; genes not listed).
- chr16:88,813,734–90,222,851, 64 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 603. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
